Somatic mutation profile of cancer-model specimen HCM-STAN-1277-C55-85B (3D Organoid, passage 10; aliquot HCM-STAN-1277-C55-85B-01D-A937-36), derived from the primary tumor of HCMI case HCM-STAN-1277-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1.
Specimen HCM-STAN-1277-C55-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5acf0104-f4ba-460c-917d-2f62d053d858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1277-C55-11B (Solid Tissue Normal), aliquot HCM-STAN-1277-C55-11B-03D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0edf48c-3d91-4525-9f83-04d1562a9a6d

The open-access MAF lists 82 somatic variants for this specimen: 56 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 24, Frame Shift Del 4, Intron 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 375/375 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 188/377 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- TP53 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 342/342 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP10 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 163/165 reads (99%) | SIFT tolerated (0.61); PolyPhen benign (0.091); catalogued as rs536202354; called by muse, mutect2, varscan2
- BAHCC1 | c.4300C>T p.R1434W | Missense Mutation (SNP) | VAF 455/993 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1376325217; called by muse, varscan2
- C19orf44 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201997646, COSV99550057; called by muse, mutect2, varscan2
- EDC4 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 16/437 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62766607; called by muse, mutect2
- EPHX1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 254/938 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771188836; called by muse, mutect2, varscan2
- KCNQ5 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100573256; called by muse, mutect2, varscan2
- LILRA6 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 193/997 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as COSV54445780; called by muse, mutect2, varscan2
- MCUR1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 219/443 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1259969818; called by muse, mutect2, varscan2
- MXD4 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 424/428 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201554312, COSV61466231; called by muse, varscan2
- TMEM151A | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 258/536 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59174299; called by muse, varscan2
- VWF | c.7760C>T p.T2587I | Missense Mutation (SNP) | VAF 138/542 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54621356; called by muse, mutect2, varscan2
- ZNF483 | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 156/719 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58517514; called by muse, mutect2, varscan2
- ABCB11 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- BTF3L4 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CACNA1F | c.3954G>T p.W1318C | Missense Mutation (SNP) | VAF 117/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP192 | c.762T>G p.F254L | Missense Mutation (SNP) | VAF 202/376 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- COL4A6 | c.2025A>C p.P675= | Splice Region (SNP) | VAF 26/492 reads (5%) | called by muse, mutect2
- DOCK3 | c.2242A>T p.T748S | Missense Mutation (SNP) | VAF 331/332 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EFCAB13 | c.2795_2810del p.I932Kfs*8 | Frame Shift Del (DEL) | VAF 182/194 reads (94%) | called by mutect2, varscan2
- EIF5 | c.440-1G>C p.X147_splice | Splice Site (SNP) | VAF 73/242 reads (30%) | called by muse, mutect2, varscan2
- FANCM | c.3046G>C p.A1016P | Missense Mutation (SNP) | VAF 96/405 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GOLGA8K | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- KANK3 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 299/591 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KCND2 | c.1819A>G p.T607A | Missense Mutation (SNP) | VAF 18/539 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); called by muse, mutect2
- KIAA2026 | c.4283A>G p.N1428S | Missense Mutation (SNP) | VAF 163/281 reads (58%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT35 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 212/416 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, varscan2
- LPIN2 | c.97_98del p.V33Hfs*33 | Frame Shift Del (DEL) | VAF 240/515 reads (47%) | called by mutect2, varscan2
- MAPK6 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC5B | c.12566A>G p.Q4189R | Missense Mutation (SNP) | VAF 343/732 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCAM1 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.193); called by muse, mutect2
- OR51I2 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.05); called by muse, mutect2
- OR8B3 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PNMA5 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 86/715 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PXDNL | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 162/353 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- RELN | c.1463del p.N488Ifs*7 | Frame Shift Del (DEL) | VAF 135/206 reads (66%) | called by mutect2, varscan2
- RPRD2 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 157/525 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEH1L | c.821_823del p.F274_D275delinsY | In Frame Del (DEL) | VAF 98/442 reads (22%) | called by mutect2, varscan2
- SON | c.3764C>T p.P1255L | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRGAP1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 238/592 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- STAG2 | c.135del p.G46Afs*25 | Frame Shift Del (DEL) | VAF 91/313 reads (29%) | called by mutect2, varscan2
- SYNE1 | c.20255A>T p.D6752V (on ENST00000367255 / NM_182961.4; = p.D6681V on NM_033071.3) | Missense Mutation (SNP) | VAF 111/280 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TENM1 | c.4684A>T p.R1562W | Missense Mutation (SNP) | VAF 475/731 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TEX14 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TPST2 | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRIM9 | c.2023G>C p.V675L | Missense Mutation (SNP) | VAF 183/592 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBA3C | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 138/283 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ULBP1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- VPS18 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 194/466 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, varscan2
- ZDBF2 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ZKSCAN3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF236 | c.2570C>G p.P857R | Missense Mutation (SNP) | VAF 301/603 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF469 | c.3114G>C p.K1038N | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZNF541 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 149/509 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ADAM8 | c.819C>G p.T273= | Silent (SNP) | VAF 132/334 reads (40%) | called by muse, mutect2, varscan2
- CARS1 | c.1026G>A p.P342= | Silent (SNP) | VAF 160/323 reads (50%) | catalogued as rs554710714; called by muse, mutect2, varscan2
- CORO2B | c.144C>T p.V48= | Silent (SNP) | VAF 172/383 reads (45%) | called by muse, mutect2, varscan2
- CYP4A22 | c.1428C>A p.L476= | Silent (SNP) | VAF 23/763 reads (3%) | catalogued as COSV53741343; called by muse, mutect2
- ENTPD1 | c.1041G>A p.G347= | Silent (SNP) | VAF 179/314 reads (57%) | called by muse, mutect2, varscan2
- HCN4 | c.3126G>A p.P1042= | Silent (SNP) | VAF 215/487 reads (44%) | catalogued as rs1057521459; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTR1E | c.946C>T p.L316= | Silent (SNP) | VAF 28/422 reads (7%) | catalogued as rs1458416028, COSV100540870; called by muse, mutect2
- IDI1 | c.42G>A p.A14= | Silent (SNP) | VAF 160/522 reads (31%) | catalogued as rs1300169620, COSV64063334; called by muse, varscan2
- KIF26A | c.4068C>T p.P1356= | Silent (SNP) | VAF 30/878 reads (3%) | called by muse, mutect2
- KIF4A | c.3027T>C p.D1009= | Silent (SNP) | VAF 118/458 reads (26%) | called by muse, mutect2, varscan2
- MALRD1 | c.1761C>A p.S587= | Silent (SNP) | VAF 138/458 reads (30%) | catalogued as rs776698947; called by mutect2, varscan2
- MSANTD4 | c.714G>A p.E238= | Silent (SNP) | VAF 126/334 reads (38%) | called by muse, mutect2, varscan2
- NLRC5 | c.3567G>A p.L1189= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- OLIG2 | c.144G>A p.P48= | Silent (SNP) | VAF 262/508 reads (52%) | catalogued as COSV60972434; called by muse, varscan2
- OR4C15 | c.747C>T p.G249= (on ENST00000314644; = p.G195= on NM_001001920.2) | Silent (SNP) | VAF 140/334 reads (42%) | catalogued as rs762788770; called by muse, mutect2
- PCDHA2 | c.1086C>T p.N362= | Silent (SNP) | VAF 429/440 reads (98%) | catalogued as rs139541416; called by muse, mutect2, varscan2
- PCDHA7 | c.1863G>A p.P621= | Silent (SNP) | VAF 413/423 reads (98%) | catalogued as COSV65344713; called by muse, mutect2, varscan2
- PEX5L | c.1665G>A p.L555= | Silent (SNP) | VAF 94/355 reads (26%) | called by muse, mutect2, varscan2
- PLCL2 | c.1959C>T p.A653= (on ENST00000615277 / NM_001144382.2; = p.A527= on NM_015184.5) | Silent (SNP) | VAF 21/596 reads (4%) | called by muse, mutect2
- PLD6 | c.60G>A p.L20= | Silent (SNP) | VAF 203/882 reads (23%) | called by muse, mutect2, varscan2
- RAD54L2 | c.4056C>T p.P1352= | Silent (SNP) | VAF 178/408 reads (44%) | catalogued as rs762101001, COSV56576909; called by muse, mutect2, varscan2
- SAMD4A | c.1209G>A p.P403= | Silent (SNP) | VAF 308/459 reads (67%) | catalogued as rs778945695, COSV51888871; called by muse, mutect2, varscan2
- SLC40A1 | c.508C>T p.L170= | Silent (SNP) | VAF 95/214 reads (44%) | called by muse, mutect2, varscan2
- WDR38 | c.183C>T p.G61= | Silent (SNP) | VAF 111/250 reads (44%) | called by muse, mutect2, varscan2
- DIP2C | c.157+1547A>C | Intron (SNP) | VAF 151/398 reads (38%) | catalogued as rs557095589; called by muse, mutect2, varscan2
- UNC5C | c.1109-2065A>T | Intron (SNP) | VAF 65/191 reads (34%) | called by muse, mutect2, varscan2
